Somatic mutation profile of tumor specimen HCM-CSHL-0074-C25-01A (aliquot HCM-CSHL-0074-C25-01A-11D-A77E-36) from HCMI case HCM-CSHL-0074-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 54.2 years (19,813 days).
Specimen HCM-CSHL-0074-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16c77df1-c5ee-498e-a2f1-53bd6fa88818.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0074-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0074-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f62f3375-ff0f-47a5-8166-10cdeea535c1

The open-access MAF lists 36 somatic variants for this specimen: 22 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 11, Frame Shift Del 3, RNA 3, Splice Site 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 133/419 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 105/663 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762340085; called by muse, mutect2, varscan2
- ARHGAP22 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 72/614 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as COSV50992174; called by muse, mutect2, varscan2
- CUX1 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 80/906 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs367708774; called by muse, mutect2
- F12 | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV53692390; called by muse, mutect2, varscan2
- FAM90A14P | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 54/3548 reads (2%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs1280625387; called by muse, mutect2
- GABRB3 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 106/779 reads (14%) | catalogued as rs942355738, COSV100159239, COSV54660326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC5AC | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 63/477 reads (13%) | SIFT tolerated (0.1); catalogued as rs577204654; called by muse, mutect2, varscan2
- OTUD7A | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 90/645 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1194383682, COSV61044236; called by muse, mutect2, varscan2
- PRKCQ | c.1445+1G>A p.X482_splice | Splice Site (SNP) | VAF 73/579 reads (13%) | catalogued as rs1190765193, COSV54111433; called by muse, mutect2, varscan2
- PRKDC | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 39/450 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377127342; called by muse, mutect2
- SMAD3 | c.830T>C p.V277A | Missense Mutation (SNP) | VAF 194/1226 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV59284555; called by muse, varscan2
- UBR4 | c.13328G>A p.R4443H | Missense Mutation (SNP) | VAF 64/471 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64384256; called by muse, mutect2, varscan2
- CCDC191 | c.2609G>C p.R870T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, varscan2
- CHD4 | c.3666A>T p.G1222= (on ENST00000357008 / NM_001363606.2; = p.G1235= on NM_001273.5) | Splice Region (SNP) | VAF 149/336 reads (44%) | called by muse, mutect2, varscan2
- CPSF3 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- NKTR | c.4032del p.T1345Hfs*130 | Frame Shift Del (DEL) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- PDGFRA | c.1454A>C p.E485A | Missense Mutation (SNP) | VAF 88/572 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TAF2 | c.3083del p.P1028Hfs*3 | Frame Shift Del (DEL) | VAF 91/864 reads (11%) | called by mutect2, pindel, varscan2
- TTN | c.58005_58009del p.S19335Rfs*11 (on ENST00000591111; = p.S11911Rfs*11 on NM_003319.4) | Frame Shift Del (DEL) | VAF 19/180 reads (11%) | called by mutect2, pindel
- WNK4 | c.3728T>C p.M1243T | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- BAHCC1 | c.2982C>T p.C994= | Silent (SNP) | VAF 46/321 reads (14%) | catalogued as rs1475816654; called by muse, mutect2, varscan2
- CDYL2 | c.927C>T p.S309= | Silent (SNP) | VAF 57/398 reads (14%) | catalogued as rs148507807; called by muse, mutect2, varscan2
- CNTN4 | c.2112G>A p.A704= | Silent (SNP) | VAF 57/460 reads (12%) | catalogued as rs759314373; called by muse, mutect2, varscan2
- DAGLA | c.2931C>T p.A977= | Silent (SNP) | VAF 43/335 reads (13%) | catalogued as rs145101853, COSV57198205, COSV99944712; called by muse, mutect2, varscan2
- FBLN2 | c.2064C>T p.P688= | Silent (SNP) | VAF 116/843 reads (14%) | catalogued as COSV99852463; called by muse, mutect2, varscan2
- IGDCC4 | c.2217G>A p.P739= | Silent (SNP) | VAF 36/372 reads (10%) | catalogued as rs748792377; called by muse, mutect2
- MBTPS2 | c.252A>C p.V84= | Silent (SNP) | VAF 136/481 reads (28%) | called by muse, mutect2, varscan2
- PAOX | c.1446G>T p.T482= | Silent (SNP) | VAF 69/527 reads (13%) | catalogued as COSV53373689, COSV53375397; called by muse, mutect2, varscan2
- PRX | c.3645C>T p.T1215= | Silent (SNP) | VAF 91/598 reads (15%) | catalogued as rs777917125, COSV52523864; called by muse, mutect2, varscan2
- TTN | c.13350C>T p.C4450= (on ENST00000591111; = p.C4404= on NM_003319.4) | Silent (SNP) | VAF 46/286 reads (16%) | catalogued as rs1217230000, COSV60205177; called by muse, mutect2, varscan2
- VARS1 | c.1920G>A p.V640= | Silent (SNP) | VAF 101/662 reads (15%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2417G>A | RNA (SNP) | VAF 46/664 reads (7%) | called by muse, mutect2
- AC139795.1 | n.1536C>T | RNA (SNP) | VAF 83/568 reads (15%) | catalogued as rs774291394; called by muse, mutect2, varscan2
- UGT2B27P | n.1439T>C | RNA (SNP) | VAF 117/950 reads (12%) | catalogued as rs769540632; called by muse, mutect2, varscan2
